Somatic mutation profile of tumor specimen HCM-BROD-0106-C71-02A (aliquot HCM-BROD-0106-C71-02A-11D-A79L-36) from HCMI case HCM-BROD-0106-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 52.7 years (19,261 days).
Specimen HCM-BROD-0106-C71-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c8057a2c-d4ab-40eb-b447-5a7392138135.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0106-C71-10A (Blood Derived Normal), aliquot HCM-BROD-0106-C71-10A-01D-A79L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/febbb47a-ac65-4e0a-b811-0b806e09ea5f

The open-access MAF lists 110 somatic variants for this specimen: 74 protein-altering or splice-affecting, 32 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 56, Silent 32, Frame Shift Del 13, Nonsense Mutation 4, Intron 3, Splice Region 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS20 | c.5559G>T p.L1853F | Missense Mutation (SNP) | VAF 51/257 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs752671454; called by muse, mutect2, varscan2
- ANKRD24 | c.418G>A p.V140M | Missense Mutation (SNP) | VAF 111/569 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.094); catalogued as rs769988640; called by muse, mutect2, varscan2
- C7orf33 | c.281C>T p.A94V | Missense Mutation (SNP) | VAF 47/617 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.005); catalogued as rs1224082344; called by muse, mutect2
- CBLL1 | c.103G>A p.A35T | Missense Mutation (SNP) | VAF 93/455 reads (20%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs1322995812, COSV99755686; called by muse, mutect2, varscan2
- CDKL4 | c.896G>A p.R299H | Missense Mutation (SNP) | VAF 96/350 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs370476409, COSV101115440; called by muse, mutect2, varscan2
- CXorf66 | c.880A>T p.T294S | Missense Mutation (SNP) | VAF 90/160 reads (56%) | SIFT tolerated (0.09); PolyPhen benign (0.14); catalogued as COSV65169631; called by muse, mutect2, varscan2
- DEUP1 | c.364C>T p.R122* | Nonsense Mutation (SNP) | VAF 41/239 reads (17%) | catalogued as rs566601356, COSV53210337; called by muse, mutect2, varscan2
- DPEP2 | c.379G>A p.V127M | Missense Mutation (SNP) | VAF 58/206 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs755590475, COSV52055998; called by muse, mutect2, varscan2
- DUOXA2 | c.73C>T p.L25F | Missense Mutation (SNP) | VAF 119/465 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as rs773820761; called by muse, mutect2, varscan2
- EFR3A | c.1206G>A p.M402I | Missense Mutation (SNP) | VAF 53/262 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.031); catalogued as COSV54459349; called by muse, mutect2, varscan2
- EGF | c.1207C>T p.R403C | Missense Mutation (SNP) | VAF 57/216 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.163); catalogued as rs776647507, COSV54479485; called by muse, mutect2, varscan2
- FAT2 | c.5327T>A p.M1776K | Missense Mutation (SNP) | VAF 88/366 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as COSV55818404; called by muse, mutect2, varscan2
- FLG | c.1960A>G p.R654G | Missense Mutation (SNP) | VAF 125/472 reads (26%) | SIFT tolerated (1); PolyPhen possibly damaging (0.879); catalogued as rs758025810, COSV64243164; called by muse, mutect2, varscan2
- HIVEP3 | c.1462C>T p.R488W | Missense Mutation (SNP) | VAF 142/543 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs750482011, COSV56024196; called by muse, mutect2, varscan2
- HUWE1 | c.11641C>T p.P3881S | Missense Mutation (SNP) | VAF 41/121 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1556916017; called by muse, mutect2, varscan2
- IL1B | c.73del p.E25Kfs*8 | Frame Shift Del (DEL) | VAF 36/299 reads (12%) | catalogued as COSV99641817; called by mutect2, pindel, varscan2
- IL1R2 | c.1012C>T p.R338C | Missense Mutation (SNP) | VAF 47/219 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.399); catalogued as rs147924293; called by muse, mutect2, varscan2
- IRX5 | c.223G>A p.A75T | Missense Mutation (SNP) | VAF 44/424 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.359); catalogued as rs1292819873; called by mutect2, varscan2
- KCNC2 | c.587C>T p.A196V | Missense Mutation (SNP) | VAF 165/617 reads (27%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV100129849, COSV54365172; called by muse, mutect2, varscan2
- MAB21L4 | c.398C>T p.S133L | Missense Mutation (SNP) | VAF 143/504 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs201848788; called by muse, mutect2, varscan2
- NIPAL2 | c.535G>A p.G179R | Missense Mutation (SNP) | VAF 75/306 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs756663093, COSV100358661; called by muse, mutect2, varscan2
- NOS1 | c.1922C>T p.A641V | Missense Mutation (SNP) | VAF 47/276 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV57616898; called by muse, mutect2, varscan2
- OPRK1 | c.688G>A p.V230I | Missense Mutation (SNP) | VAF 58/372 reads (16%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.927); catalogued as rs186551684; called by muse, mutect2, varscan2
- OR5AP2 | c.382C>T p.R128C | Missense Mutation (SNP) | VAF 62/240 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.097); catalogued as rs564090082, COSV57257559; called by muse, mutect2, varscan2
- OTOGL | c.1528G>A p.V510M (on ENST00000547103; = p.V501M on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 93/337 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.399); catalogued as rs747153629; called by muse, mutect2, varscan2
- PALM3 | c.820G>A p.V274M (on ENST00000340790; = p.V289M on NM_001145028.2) | Missense Mutation (SNP) | VAF 127/737 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.561); catalogued as rs576725512; called by muse, mutect2, varscan2
- PCLO | c.13218G>T p.R4406S | Missense Mutation (SNP) | VAF 98/556 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs767015823, COSV100438797; called by muse, mutect2, varscan2
- PLOD1 | c.265G>A p.A89T | Missense Mutation (SNP) | VAF 46/302 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.079); catalogued as rs886039207; called by muse, varscan2
- PRPF40B | c.997A>G p.K333E (on ENST00000380281; = p.K327E on NM_012272.3) | Missense Mutation (SNP) | VAF 125/399 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1317868299; called by muse, mutect2, varscan2
- PTGES | c.412G>A p.A138T | Missense Mutation (SNP) | VAF 107/389 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.028); catalogued as rs753334822, COSV61393658; called by muse, mutect2, varscan2
- SCNN1G | c.68C>T p.P23L | Missense Mutation (SNP) | VAF 92/410 reads (22%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.998); catalogued as rs368523916; called by muse, varscan2
- SGCZ | c.662G>A p.R221H | Missense Mutation (SNP) | VAF 72/306 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); catalogued as rs772544113, COSV101170775, COSV66033304; called by muse, mutect2, varscan2
- TAFA2 | c.235C>T p.R79* | Nonsense Mutation (SNP) | VAF 71/256 reads (28%) | catalogued as COSV101352965, COSV101353930, COSV69178548; called by muse, mutect2, varscan2
- TBX19 | c.1090G>A p.G364R | Missense Mutation (SNP) | VAF 98/363 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.3); catalogued as rs199644548, COSV100892370; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TESPA1 | c.814C>T p.R272* (on ENST00000316577 / NM_001098815.3; = p.R134* on NM_014796.2 and 5 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 130/482 reads (27%) | catalogued as rs759038034; called by muse, mutect2, varscan2
- VPS13B | c.8145del p.Q2716Sfs*26 | Frame Shift Del (DEL) | VAF 25/259 reads (10%) | catalogued as COSV100663690; called by mutect2, pindel, varscan2
- ZSCAN5C | c.826G>A p.V276I | Missense Mutation (SNP) | VAF 56/594 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.428); catalogued as rs762862197; called by muse, mutect2
- A2ML1 | c.176del p.K59Rfs*8 | Frame Shift Del (DEL) | VAF 67/428 reads (16%) | called by mutect2, pindel, varscan2
- AFF3 | c.3001G>A p.A1001T | Missense Mutation (SNP) | VAF 48/311 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- AJAP1 | c.1177G>C p.D393H | Missense Mutation (SNP) | VAF 45/409 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ALKBH5 | c.9del p.A4Pfs*14 | Frame Shift Del (DEL) | VAF 43/424 reads (10%) | called by mutect2, pindel*
- ATP1A4 | c.1694_1698del p.L565Sfs*3 | Frame Shift Del (DEL) | VAF 34/370 reads (9%) | called by mutect2, pindel
- BICDL1 | c.494G>A p.G165D | Missense Mutation (SNP) | VAF 92/395 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- CCDC138 | c.1352G>C p.R451T | Missense Mutation (SNP) | VAF 67/284 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- CDH22 | c.638G>T p.G213V | Missense Mutation (SNP) | VAF 43/369 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- CREB3L4 | c.895T>G p.L299V | Missense Mutation (SNP) | VAF 30/274 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- DISP2 | c.2125T>G p.W709G | Missense Mutation (SNP) | VAF 73/726 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.295); called by muse, mutect2, varscan2
- DSE | c.386A>G p.Y129C | Missense Mutation (SNP) | VAF 47/242 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- EGFR | c.1616G>A p.C539Y | Missense Mutation (SNP) | VAF 1823/4748 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAF2 | c.44A>G p.E15G | Missense Mutation (SNP) | VAF 55/419 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- FAM83B | c.3002A>G p.Q1001R | Missense Mutation (SNP) | VAF 42/217 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- HEG1 | c.3233_3234del p.F1078Sfs*2 | Frame Shift Del (DEL) | VAF 26/280 reads (9%) | called by mutect2, pindel
- HUWE1 | c.11642C>A p.P3881H | Missense Mutation (SNP) | VAF 41/121 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- KLHL8 | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 52/353 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRP6 | c.826del p.Q276Nfs*23 | Frame Shift Del (DEL) | VAF 30/264 reads (11%) | called by mutect2, pindel, varscan2
- MTOR | c.3030A>G p.E1010= | Splice Region (SNP) | VAF 14/190 reads (7%) | called by muse, mutect2
- PCDHB15 | c.1777G>T p.D593Y | Missense Mutation (SNP) | VAF 56/582 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PTCD1 | c.1439A>G p.E480G | Missense Mutation (SNP) | VAF 79/594 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- SC5D | c.255del p.W86Gfs*2 | Frame Shift Del (DEL) | VAF 49/335 reads (15%) | called by mutect2, pindel, varscan2
- SGMS1 | c.350A>C p.K117T | Missense Mutation (SNP) | VAF 117/310 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- SLCO5A1 | c.310A>T p.T104S | Missense Mutation (SNP) | VAF 61/457 reads (13%) | SIFT tolerated, low confidence (0.83); PolyPhen benign (0.01); called by muse, varscan2
- STK36 | c.402_403delinsT p.K135Rfs*16 | Frame Shift Del (DEL) | VAF 25/243 reads (10%) | called by pindel, varscan2*
- SYNE4 | c.518G>A p.W173* | Nonsense Mutation (SNP) | VAF 154/838 reads (18%) | called by muse, mutect2, varscan2
- TAF4 | c.2504A>G p.N835S | Missense Mutation (SNP) | VAF 45/341 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- TFAP2E | c.607_608del p.A203Qfs*13 | Frame Shift Del (DEL) | VAF 71/451 reads (16%) | called by mutect2, pindel, varscan2
- TFG | c.1130G>A p.G377E | Missense Mutation (SNP) | VAF 85/404 reads (21%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- THSD7B | c.545T>A p.V182E | Missense Mutation (SNP) | VAF 36/318 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- THSD7B | c.1760C>G p.P587R | Missense Mutation (SNP) | VAF 76/300 reads (25%) | SIFT tolerated (0.43); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- TRIM63 | c.415G>A p.V139M | Missense Mutation (SNP) | VAF 83/379 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.213); called by muse, mutect2, varscan2
- TRPV4 | c.1635_1638del p.I545Mfs*15 | Frame Shift Del (DEL) | VAF 28/251 reads (11%) | called by mutect2, pindel, varscan2
- TUT4 | c.3805C>T p.L1269F | Missense Mutation (SNP) | VAF 39/174 reads (22%) | SIFT tolerated (0.58); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- UGT2B15 | c.566T>G p.L189R | Missense Mutation (SNP) | VAF 71/327 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.652); called by muse, mutect2, varscan2
- ZBTB21 | c.2989del p.Q997Sfs*100 | Frame Shift Del (DEL) | VAF 102/466 reads (22%) | called by mutect2, pindel, varscan2
- ZNF433 | c.886del p.S296Pfs*375 | Frame Shift Del (DEL) | VAF 54/496 reads (11%) | called by mutect2, varscan2
- AC069544.2 | c.286T>C p.L96= | Silent (SNP) | VAF 83/238 reads (35%) | called by muse, mutect2, varscan2
- APOA4 | c.1152G>A p.Q384= | Silent (SNP) | VAF 42/464 reads (9%) | called by muse, mutect2
- ATP8A2 | c.2634C>T p.C878= | Silent (SNP) | VAF 66/348 reads (19%) | catalogued as rs1412809979; called by muse, mutect2, varscan2
- BTNL3 | c.1353C>T p.D451= | Silent (SNP) | VAF 80/336 reads (24%) | catalogued as rs771319366; called by muse, varscan2
- CCR1 | c.27C>T p.D9= | Silent (SNP) | VAF 81/298 reads (27%) | called by muse, mutect2, varscan2
- CDH22 | c.639C>T p.G213= | Silent (SNP) | VAF 43/367 reads (12%) | catalogued as rs1229758926, COSV64837322; called by muse, mutect2, varscan2
- CDK13 | c.4377C>T p.N1459= | Silent (SNP) | VAF 56/313 reads (18%) | called by muse, mutect2, varscan2
- CENPVL3 | c.27T>C p.A9= | Silent (SNP) | VAF 79/301 reads (26%) | called by muse, mutect2, varscan2
- COMTD1 | c.726C>T p.D242= | Silent (SNP) | VAF 100/378 reads (26%) | called by muse, mutect2, varscan2
- DNAH10 | c.10374C>T p.S3458= (on ENST00000409039; = p.S3397= on NM_207437.3) | Silent (SNP) | VAF 111/445 reads (25%) | called by muse, mutect2, varscan2
- DNAH14 | c.453C>T p.A151= | Silent (SNP) | VAF 49/646 reads (8%) | catalogued as rs1426079712; called by muse, mutect2
- EPHA8 | c.27C>T p.P9= | Silent (SNP) | VAF 31/228 reads (14%) | called by muse, mutect2, varscan2
- ETV1 | c.1065C>G p.A355= | Silent (SNP) | VAF 36/540 reads (7%) | catalogued as rs1027136314; called by muse, mutect2
- GFRA2 | c.1086C>T p.N362= | Silent (SNP) | VAF 51/484 reads (11%) | catalogued as rs117552912; called by muse, mutect2
- GRM7 | c.1470G>A p.P490= | Silent (SNP) | VAF 104/415 reads (25%) | catalogued as rs138702582; called by muse, mutect2, varscan2
- HECTD4 | c.519G>A p.L173= | Silent (SNP) | VAF 106/415 reads (26%) | called by muse, mutect2, varscan2
- IGHMBP2 | c.1645A>C p.R549= | Silent (SNP) | VAF 36/284 reads (13%) | called by muse, mutect2, varscan2
- LILRA4 | c.699C>T p.V233= | Silent (SNP) | VAF 140/540 reads (26%) | catalogued as rs564361750; called by muse, mutect2, varscan2
- MXRA5 | c.7539C>T p.S2513= | Silent (SNP) | VAF 160/282 reads (57%) | catalogued as rs753094455; called by muse, mutect2, varscan2
- NCF2 | c.1443G>A p.G481= | Silent (SNP) | VAF 64/246 reads (26%) | called by muse, mutect2, varscan2
- PCDHGA8 | c.1722C>T p.G574= | Silent (SNP) | VAF 157/716 reads (22%) | catalogued as COSV53913414; called by muse, mutect2, varscan2
- PTPN18 | c.771C>T p.D257= | Silent (SNP) | VAF 95/406 reads (23%) | called by muse, mutect2, varscan2
- SCN5A | c.1578C>T p.R526= | Silent (SNP) | VAF 114/399 reads (29%) | catalogued as rs981474076; called by muse, mutect2, varscan2
- SLC35B3 | c.945G>A p.L315= | Silent (SNP) | VAF 70/312 reads (22%) | called by muse, mutect2, varscan2
- SLC3A1 | c.834T>C p.F278= | Silent (SNP) | VAF 34/432 reads (8%) | called by muse, mutect2
- SNX8 | c.1302C>T p.N434= | Silent (SNP) | VAF 86/389 reads (22%) | catalogued as rs373187532; called by muse, mutect2, varscan2
- TERT | c.2793C>T p.C931= | Silent (SNP) | VAF 121/462 reads (26%) | catalogued as rs764925909, COSV57228211; ClinVar: likely benign; called by muse, mutect2, varscan2
- THSD7B | c.2643G>A p.T881= | Silent (SNP) | VAF 64/314 reads (20%) | catalogued as rs191103781; called by muse, mutect2, varscan2
- TSPAN8 | c.666G>T p.L222= | Silent (SNP) | VAF 72/255 reads (28%) | called by muse, mutect2, varscan2
- TTC6 | c.825G>A p.T275= | Silent (SNP) | VAF 72/577 reads (12%) | called by muse, mutect2, varscan2
- WDCP | c.1983G>A p.P661= | Silent (SNP) | VAF 67/278 reads (24%) | catalogued as rs769632619, COSV54591630; called by muse, mutect2, varscan2
- ZNF17 | c.1260G>A p.G420= | Silent (SNP) | VAF 48/403 reads (12%) | called by muse, mutect2, varscan2
- COL18A1-AS2 | chr21:45405446 G>A | 3'Flank (SNP) | VAF 65/584 reads (11%) | called by muse, mutect2, varscan2
- PHF21B | c.55-188C>T | Intron (SNP) | VAF 133/507 reads (26%) | called by muse, mutect2, varscan2
- RAB11FIP5 | c.1569-4536C>T | Intron (SNP) | VAF 55/367 reads (15%) | called by muse, mutect2, varscan2
- RIMBP2 | c.2362-1849C>T | Intron (SNP) | VAF 165/621 reads (27%) | catalogued as rs544641588; called by muse, mutect2, varscan2
